Somatic mutation profile of tumor specimen TCGA-10-0933-01A (aliquot TCGA-10-0933-01A-01W-0421-09) from TCGA case TCGA-10-0933, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.8 years (28,433 days).
Specimen TCGA-10-0933-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 221f3ea1-085b-4b8a-bbea-b9ad4b50f611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0933-11A (Solid Tissue Normal), aliquot TCGA-10-0933-11A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eb709e2-8595-4cc6-863e-af8d9dd704f6

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 14, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 235/251 reads (94%) | hotspot (GDC flag); catalogued as rs137853293, CM900196, COSV57296164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as rs771542253, COSV60917951; called by muse, mutect2, varscan2
- AK9 | c.172C>A p.R58S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.828); catalogued as COSV53423700, COSV99572572; called by muse, mutect2, varscan2
- ATP9A | c.855T>A p.N285K | Missense Mutation (SNP) | VAF 93/562 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58771465; called by muse, mutect2, varscan2
- CAMTA2 | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as COSV61838058; called by muse, mutect2, varscan2
- CCM2L | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52952510; called by muse, mutect2, varscan2
- CD93 | c.1373G>A p.W458* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as rs766261091, COSV99849550; called by muse, mutect2, varscan2
- CENPF | c.3841A>G p.T1281A | Missense Mutation (SNP) | VAF 113/190 reads (59%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs1223033692, COSV65278740; called by muse, mutect2, varscan2
- CENPQ | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV59922129; called by muse, mutect2, varscan2
- CLTCL1 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99595798; called by muse, mutect2
- DNM1 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV57855769; called by muse, mutect2, varscan2
- DTX1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs759015998, COSV55659494; called by muse, mutect2, varscan2
- FAM47C | c.1801A>G p.T601A | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV63730156; called by muse, mutect2, varscan2
- FLG | c.11675G>A p.R3892Q | Missense Mutation (SNP) | VAF 91/352 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs372348813, COSV64242241; called by muse, mutect2, varscan2
- HHIP | c.1423+2T>C p.X475_splice | Splice Site (SNP) | VAF 186/293 reads (63%) | catalogued as COSV56843795; called by muse, mutect2, varscan2
- KLHDC7A | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV68770919; called by muse, mutect2, varscan2
- MAOB | c.820T>A p.F274I | Missense Mutation (SNP) | VAF 185/427 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV65206771; called by muse, mutect2, varscan2
- MLLT3 | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 130/439 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV63501988; called by muse, varscan2
- MXRA5 | c.2272G>A p.V758I | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV54249199; called by muse, mutect2, varscan2
- OVCH1 | c.3251G>T p.W1084L | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.013); catalogued as COSV58967781; called by muse, mutect2, varscan2
- PEAK1 | c.3593G>A p.S1198N | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56942623; called by muse, mutect2, varscan2
- PGBD2 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61401071; called by muse, mutect2, varscan2
- PROSER3 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.775); catalogued as rs755976528, COSV56554153; called by muse, mutect2
- PSMB4 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV51853158; called by muse, mutect2, varscan2
- RHOA | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV101371152, COSV69043583, COSV99069255; called by muse, mutect2, varscan2
- SAE1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs538083905, COSV54298820; called by muse, mutect2, varscan2
- STRIP1 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV63931206; called by muse, mutect2, varscan2
- UNC119B | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.216); catalogued as COSV60865754; called by muse, mutect2
- VPS16 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 81/138 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66799036; called by muse, mutect2, varscan2
- ZFAND2A | c.330del p.M110Ifs*? | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as COSV57181093; called by mutect2, pindel, varscan2
- ZFC3H1 | c.1597A>G p.M533V | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV66432650; called by muse, mutect2, varscan2
- ZNF133 | c.1418G>T p.R473L (on ENST00000316358 / NM_001352454.2; = p.R472L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315454; called by muse, varscan2
- ZNF512 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 89/141 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.121); catalogued as COSV62678126; called by muse, mutect2, varscan2
- AHNAK2 | c.11776G>A p.D3926N | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2
- NHSL2 | c.1288G>T p.V430L (on ENST00000510661; = p.V796L on NM_001013627.2) | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2
- PRSS22 | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.5); called by mutect2, varscan2
- SRPX2 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2
- TP53 | c.394_398del p.K132Vfs*15 | Frame Shift Del (DEL) | VAF 21/28 reads (75%) | called by mutect2, pindel, varscan2
- VPS26A | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ALG2 | c.894C>T p.T298= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV99445705; called by muse, mutect2
- BNC2 | c.1143A>G p.T381= | Silent (SNP) | VAF 72/224 reads (32%) | catalogued as COSV66156482; called by muse, mutect2, varscan2
- CACNA1F | c.4242C>T p.S1414= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- COL6A3 | c.3021A>G p.P1007= | Silent (SNP) | VAF 146/460 reads (32%) | catalogued as COSV55107595; called by muse, mutect2, varscan2
- DYRK1B | c.156C>T p.L52= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs763244310, COSV55683941; called by muse, mutect2, varscan2
- EGFL8 | c.255G>A p.V85= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- KCNC1 | c.1308G>A p.V436= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99789706; called by muse, mutect2, varscan2
- LCN12 | c.159C>T p.F53= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100861341; called by muse, varscan2
- MAX | c.369C>T p.Y123= | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as COSV99408639; called by muse, mutect2, varscan2
- NLRP8 | c.699C>T p.Y233= | Silent (SNP) | VAF 128/408 reads (31%) | catalogued as rs377108884; called by muse, mutect2, varscan2
- PTPRG | c.117C>T p.H39= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs753540838, COSV55661375; called by muse, mutect2, varscan2
- SPNS1 | c.297C>T p.L99= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1426957851, COSV57955478; called by muse, mutect2, varscan2
- TRIO | c.4923C>T p.A1641= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV100710923; called by muse, mutect2, varscan2
- UGT8 | c.483C>T p.G161= | Silent (SNP) | VAF 44/77 reads (57%) | catalogued as rs368584974, COSV60420654; called by muse, mutect2, varscan2
- MIR412 | n.79G>A | RNA (SNP) | VAF 8/38 reads (21%) | catalogued as rs368964407; called by muse, mutect2
